Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3H2, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3H2-01A (Primary Tumor).

[page 1 of 4]
Criteria	OMF- Priy. Malig. SFG. @ Neck
Diagnosis Discrepancy	Classical
Prior Tumor Discrepancy	Classical
Prior Metastasis Discrepancy	Classical
Prior Metastasis Discrepancy	Classical
Discrepancy Primary Noted	Classical

Redacted Pathology

port

Pathology,

DOB:

Sex: M

Physician:

Accession:

Collected:

Received:

Case type: Surgical Case

cc:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

(A) RIGHT ANTERIOR SCALENE LYMPH NODE:

One lymph node with granulomatous inflammation, no tumor present.

(B) RIGHT NECK CONTENTS, LEVEL 2, 3 AND 4:

BENIGN-LOOKING THYROID TISSUE METASTATIC TO ONE OF TEN LEVEL 2 LYMPH NODES AND THREE OF FIVE LEVEL 3 LYMPH NODES.

Six level 4 lymph nodes, no tumor present.

(C) LEFT POSTERIOR CAROTID SPACE MASS:

Thrombosed vessel, no tumor present.

(D) SUBMANDIBULAR GANGLION:

Ganglion and salivary gland, no tumor present.

(E) LEFT COMPREHENSIVE NECK DISSECTION, RIGHT LEVEL 1:

INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA OF MANDIBLE, 4.5 CM.

METASTATIC SQUAMOUS CELL CARCINOMA IN ONE OF ONE LEVEL 2 LYMPH NODE, 6.0 CM WITH EXTRANODAL EXTENSION INTO FIBROADIPOSE TISSUE AND SALIVARY GLAND.

Four level I lymph node, three level III lymph nodes and five level IV lymph nodes, no tumor present.

Left floor of mouth margin with focal mild dysplasia.

All of the margins free of tumor.

(F) RIGHT SUPERIOR PARATHYROID GLAND:

Parathyroid.

(G) TOTAL THYROIDECTOMY AND PARATRACHEAL LYMPH NODE DISSECTION:

SMALL FOCUS OF FOLLICULAR VARIANT PAPILLARY CARCINOMA, 3.0 MM.

Multiple adenomatous hyperplasia.

Entire report and diagnosis completed by

1CD-0-3

(90%)

Path: carcinoma, papillary, follicular variant 8340/3

CQCF: carcinoma, papillary and follicular 8340/3

Site: thyroid, NOS C73.9 11/30/11

GROSS DESCRIPTION

(A) RIGHT ANTERIOR SCALENE LYMPH NODE - One lymph node (0.7 x 0.4 x 0.4 cm).

SECTION CODE: A, submitted in toto for frozen section.

*FS/DX: GRANULOMATOUS INFLAMMATION. CARCINOMA NOT IDENTIFIED.

(B) RIGHT NECK CONTENTS, LEVEL 2, 3, AND 4 - A tan-yellow lobulated soft tissue fragment (10.2 x 5.5 x 2.8 cm). Multiple lymph nodes are identified measuring between 0.3 and 3.0 cm in maximum diameter. The largest possible lymph node is identified at Level III measuring 3.0 x 1.5 x 1.5 cm. A second large lymph node is identified at level 3 measuring 2.5 x 1.0 x 0.8 cm. The lymph nodes are entirely submitted.

SECTION CODE: B1, representative section from largest possible lymph node for frozen section; B2, representative sections from second largest lymph node for frozen section; B3, a second representative section from the largest possible lymph

[page 2 of 4]
Surgical Pathology Report

Department of Pathology,

Tel: _____

DOB: _____

Physician: _____

Sex: M

Collected: _____

Pathologist: _____

Accession _____

Received: _____

Case type: Surgical Case

cc: _____

node for frozen section; B4, three lymph nodes (Level II); B5, three lymph nodes Level II; B6, one lymph node bisected, Level II; B7, three lymph nodes, Level II; B8, one lymph node, Level III; B9, remainder of the second largest lymph node, Level III; B10, one lymph node bisected, Level III; B11, one lymph node bisected, Level III; B12, one lymph node bisected, Level III; B13-B16, remainder of largest possible lymph node, Level III; B17, Two possible lymph nodes, Level IV; B18, one lymph node bisected, Level IV; B19, multiple possible lymph nodes, Level IV; B20, one lymph node bisected, Level IV; B21, two possible lymph nodes, Level IV.

***FS/DX: BENIGN LOOKING THYROID TISSUE (B1, B3) METASTATIC TO 1/1 LYMPH NODE. ONE LYMPH NODE NEGATIVE (B2).**

(C) **LEFT POSTERIOR CAROTID SPACE MASS** – One oval-shaped portion of yellow-tan tissue 3.0 x 2.5 x 2.0 cm. The cut surface is pink-tan and hemorrhagic with cystic spaces. Three representative sections submitted for frozen section. The remainder of the specimen is submitted in cassettes C4-C12.

***FS/DX: CONSISTENT WITH THROMBOSED VESSEL. ADDITIONAL TWO SECTIONS SAME.**

(D) **SUBMANDIBULAR GANGLION** - One portion of tan soft tissue 0.5 x 0.5 x 0.5 cm. Entirely submitted for frozen section.

***FS/DX: GANGLION AND SALIVARY GLAND.**

(E) **LEFT COMPREHENSIVE NECK DISSECTION, RIGHT LEVEL 1** - Hemimandibulectomy and floor of mouth dissection, partial mandibulectomy with left neck dissection and partial right dissection with overall measurements of 8.0 x 5.0 x 4.0 cm. The left neck dissection measures 11.0 x 6.0 x 4.5 cm and includes a large firm mass in the left submandibular gland. The mandible contains multiple teeth with golden crowns with missing incisors and canines with ulcerated and fungating lesions measuring approximately 4.5 x 3.0 x 1.5 cm extending into the anterior soft tissue. The mucosa and the soft tissue are grossly uninvolved.

Multiple lymph nodes are identified in the left neck dissection measuring between 0.5 and 6.0 cm in maximum diameter. The largest lymph node is tan-yellow, soft, and necrotic. Multiple lymph nodes are identified in the right neck dissection (level 1) measuring between 0.5 and 1.5 cm in maximum diameter.

SECTION CODE: E1-E2, floor of mouth, margin submitted for frozen section; E3-E6, anterior mucosal margin submitted for frozen section; E7-E18, tumor submitted from right to left; E19-E22, representative sections from largest necrotic lymph node (right neck, level 2); E23, one lymph node bisected (right neck, level 3); E24, one lymph node bisected (right neck, level 3); E25-E30, large nodule serially sectioned submitted in its entirety (right neck, level 3); E31-E32, one lymph node bisected (right neck, level 3); E33, three lymph nodes (right neck, level 4); E34, three lymph nodes (right neck, level 4); E35, three lymph nodes (right neck, level 4); E36, two lymph nodes (left neck, level 1); E37, one lymph node bisected (left neck, level 1); E38-E39, one large lymph node serially sectioned (left neck, level 1); E40, left salivary gland, representative section.

***FS/DX: E1, NEGATIVE. E2, DYSPLASIA. E3-E6, NEGATIVE.**

(F) **RIGHT SUPERIOR PARATHYROID GLAND** - One portion of pink-tan soft tissue 0.5 x 0.5 x 0.5 cm. Submitted entirely for frozen section in one cassette.

***FS/DX: PARATHYROID.**

(G) **TOTAL THYROIDECTOMY AND PARATRACHEAL LYMPH NODE DISSECTION** - A product of total thyroidectomy with the right lobe (6.5 x 4.5 x 2.0 cm), the left lobe (4.0 x 3.0 x 1.5 cm). In the lower lateral pole of the right lobe, a well-circumscribed firm mass approximately 2.5 x 1.7 x 2.0 cm is noted. The largest is completely covered by a fibrous capsule and attached to the thyroid medially. Another firm, at least 1.0 cm, ill-defined mass in the upper left pole of the right thyroid lobe is noted. No other nodule or tumors are noted in the thymus or the left lobe. On sectioning, a well-circumscribed, light tan lesion approximately 1.5 cm is noted in the upper superior aspect of the thyroid lobe. Another well-circumscribed, well-defined, light tan lesion is noted on the opposite side of the lobe and the nodule measures approximately 1.2 cm. On sectioning, the nodule in the medial aspect of the right lobe is centrally calcified. Multiple small colloid nodules and adenomas are also noted in the left lobe ranging in size from 0.2-1.0 cm. The specimen is submitted as follows: G1-G16, sequential sectioning of the right lobe from superior to inferior including the nodule and the cystic lesion; G17, representative section of the isthmus; G18-G25, sequential sectioning of the left

Page 2 of 4	
Surgical Pathology Report	
File under: Pathology	

[page 3 of 4]
Surgical Pathology Report

Department of Pathology,
Tel: _____

DOB: _____

Sex: M

Physician: _____

Accession _____

Collected: _____

Received: _____

Pathologist: _____

Case type: Surgical Case

cc: _____

lobe from superior to inferior; G26. nodule attached to the lower pole of the right lobe; G27, G28, lymph nodes from the paratracheal adipose tissue.

(H) TEETH - Multiple teeth, 3.5 x 1.5 x 1.0 cm in aggregate. No distinct soft tissues are identified attached to the teeth. Specimen appears grossly consistent with teeth and is submitted for gross identification only.

CLINICAL HISTORY

Invasive squamous cell carcinoma of mandible.

SNOMED CODES

T-B6000, T-51200, T-11180, M-83403, M-80703

Released by: _____

Surgical Pathology Report		Page 3 of 4
File under: Pathology		

[page 4 of 4]
Surgical Pathology Report

Department of Pathology

Te

DOB:

Sex: M

Physician:

Accession

Collected:

Received:

cc:

Pathologist:

Case type: Surgical Case

ADDENDUM

DIAGNOSIS:

(G) TOTAL THYROIDECTOMY AND PARATRACHEAL LYMPH NODE DISSECTION:
FOLLICULAR VARIANT OF PAPILLARY CARCINOMA (1.7 CM).

Entire report and diagnosis completed by

Released by:

Surgical Pathology Report		Page 4 of 4
File under: Pathology		

Source: NCI Genomic Data Commons file d54bb721-e39a-4c87-823b-43093e528d74 (TCGA-EL-A3H2.BB009B7A-967E-441F-B73E-0463B3BEEA73.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).